Somatic mutation profile of tumor specimen TCGA-CV-5436-01A (aliquot TCGA-CV-5436-01A-01D-1512-08) from TCGA case TCGA-CV-5436, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 65.5 years (23,923 days).
Specimen TCGA-CV-5436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 740c54e3-30e4-4237-9afd-d1b7921cb72e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5436-10A (Blood Derived Normal), aliquot TCGA-CV-5436-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a15f8f9-b03e-4439-b102-fa846e389d8c

The open-access MAF lists 105 somatic variants for this specimen: 75 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 25, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, 3'Flank 1, Splice Region 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ANKRD30A | c.3847C>T p.H1283Y (on ENST00000611781; = p.H1227Y on NM_052997.2) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV100653582, COSV64621181; called by muse, mutect2, varscan2
- APOB | c.6218T>C p.F2073S | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265760, COSV99268000; called by muse, mutect2, varscan2
- ARFGEF2 | c.4080G>C p.K1360N | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100904269; called by muse, mutect2, varscan2
- ATG13 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100365762; called by muse, mutect2, varscan2
- ATG4D | c.413C>G p.S138W | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100521027, COSV58762733; called by muse, mutect2
- AXDND1 | c.1720C>G p.R574G | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100858430, COSV62645939; called by muse, mutect2, varscan2
- BICD1 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99862440; called by muse, mutect2, varscan2
- BTBD10 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs1180500594, COSV53399425; called by muse, mutect2, varscan2
- CDAN1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as COSV99141742; called by muse, mutect2, varscan2
- CDYL | c.395A>T p.N132I (on ENST00000328908 / NM_001368125.1; = p.N78I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100189412; called by muse, mutect2, varscan2
- CNOT1 | c.6888T>A p.N2296K | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV54700166, COSV99543180; called by muse, varscan2
- COL22A1 | c.4456C>T p.Q1486* | Nonsense Mutation (SNP) | VAF 110/198 reads (56%) | catalogued as COSV100278654; called by muse, mutect2, varscan2
- CPAMD8 | c.1786G>A p.V596M (on ENST00000651564; = p.V549M on NM_015692.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373943547; called by muse, mutect2, varscan2
- CTNND2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs745751289, COSV100476970, COSV58909274; called by muse, mutect2, varscan2
- CYP2R1 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV100584925; called by muse, mutect2, varscan2
- DCLK1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55192408; called by muse, mutect2, varscan2
- DIP2C | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99791295; called by muse, mutect2, varscan2
- DNAJC14 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100423606, COSV57912500; called by muse, mutect2, varscan2
- DOCK10 | c.4567A>T p.M1523L | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99289638; called by muse, mutect2, varscan2
- EIF2AK1 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV99551945; called by muse, mutect2, varscan2
- EPHA7 | c.2672A>T p.D891V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100993761; called by muse, varscan2
- EPHA7 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV65185522; called by muse, varscan2
- EYS | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV60985879; called by muse, mutect2, varscan2
- FOXS1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs773930926, COSV54065263; called by muse, mutect2, varscan2
- FUT9 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV100133657; called by muse, mutect2, varscan2
- GNAZ | c.335del p.G112Afs*46 | Frame Shift Del (DEL) | VAF 60/223 reads (27%) | catalogued as COSV50737965; called by mutect2, pindel, varscan2
- HACL1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1280761034, COSV100337259; called by muse, mutect2, varscan2
- HHIPL2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.716); catalogued as COSV100596867; called by muse, mutect2, varscan2
- IRX5 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs764428767, COSV100315836; called by muse, mutect2, varscan2
- ITGAX | c.3199G>T p.V1067L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99191732; called by muse, mutect2, varscan2
- JPH4 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100689285; called by muse, mutect2
- KCTD3 | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99379293; called by muse, mutect2, varscan2
- KCTD4 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV100476916; called by muse, mutect2, varscan2
- KIAA1109 | c.2276A>G p.Y759C | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99164097; called by muse, mutect2, varscan2
- LCP1 | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59942390; called by muse, mutect2, varscan2
- MAL | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs745729561, COSV59430623; called by muse, mutect2, varscan2
- MARCHF6 | c.2699C>T p.S900L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56881021, COSV99929735; called by muse, mutect2, varscan2
- MROH1 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100395800; called by muse, mutect2, varscan2
- MSR1 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100027326; called by muse, mutect2, varscan2
- MTMR2 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100656730; called by muse, mutect2, varscan2
- NMI | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99693383; called by muse, mutect2, varscan2
- NOTCH1 | c.1433G>A p.C478Y | Missense Mutation (SNP) | VAF 118/149 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53040234, COSV53069801; called by muse, mutect2, varscan2
- OR5L1 | c.818T>G p.V273G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs768409934, COSV100450058; called by muse, mutect2, varscan2
- PAN2 | c.3325A>G p.M1109V (on ENST00000425394 / NM_001127460.3; = p.M1105V on NM_014871.5) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1208822059, COSV99228293; called by muse, mutect2, varscan2
- PHF2 | c.2682G>C p.K894N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100823174, COSV63678728; called by muse, mutect2, varscan2
- PIK3R4 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs896820380, COSV100768415; called by muse, mutect2, varscan2
- PLA2G3 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99311714; called by muse, mutect2, varscan2
- POLQ | c.3871C>G p.L1291V | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99952303; called by muse, mutect2, varscan2
- PRKDC | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs921811356, COSV100040766; called by muse, mutect2, varscan2
- RNPEP | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV99821492; called by muse, mutect2, varscan2
- RP1 | c.1180A>G p.M394V | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs763523179, COSV99607575; called by muse, mutect2, varscan2
- RSPO2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV52656184, COSV99409646; called by muse, mutect2, varscan2
- SCYL1 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.057); catalogued as COSV99534138; called by muse, mutect2, varscan2
- SH3BP4 | c.2361C>A p.C787* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100749181, COSV60644720; called by muse, mutect2, varscan2
- SLC27A6 | c.1565G>C p.R522T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV99322731; called by muse, mutect2, varscan2
- SLC9A3R2 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757611488, COSV54592482, COSV99526342; called by muse, mutect2, varscan2
- SOBP | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100433169; called by muse, mutect2, varscan2
- SORBS1 | c.766C>T p.R256C (on ENST00000361941 / NM_001034954.2; = p.R224C on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as rs761335103, COSV99528071; called by muse, mutect2, varscan2
- STX1A | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99767486; called by muse, mutect2, varscan2
- SYNCRIP | c.1278A>G p.Q426= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100784206; called by muse, mutect2, varscan2
- SZT2 | c.7877C>G p.A2626G (on ENST00000634258 / NM_001365999.1; = p.A2569G on NM_015284.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV100987322; called by muse, mutect2, varscan2
- TMEM154 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs1325253780, COSV100433105; called by mutect2, varscan2
- TMPRSS6 | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs757612914, COSV100695790; called by muse, mutect2, varscan2
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 94/310 reads (30%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TTN | c.36319G>C p.V12107L (on ENST00000591111; = p.V4683L on NM_003319.4) | Missense Mutation (SNP) | VAF 30/198 reads (15%) | PolyPhen probably damaging (0.99); catalogued as COSV100614369; called by muse, mutect2, varscan2
- TTN | c.15478A>G p.T5160A (on ENST00000591111; = p.T4233A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | PolyPhen benign (0); catalogued as rs756878354, COSV100614373; called by muse, mutect2, varscan2
- UTRN | c.2341A>C p.K781Q | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.432); catalogued as COSV100839950; called by muse, mutect2, varscan2
- WBP11 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 141/427 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.231); catalogued as rs150908147; called by muse, mutect2, varscan2
- WDR76 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs868373046, COSV55476639; called by muse, mutect2
- ZNF184 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99279680; called by muse, mutect2, varscan2
- ZSCAN22 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs768621173, COSV61639658, COSV61639676; called by muse, mutect2, varscan2
- PARP2 | c.1622_1623insGGC p.A541dup | In Frame Ins (INS) | VAF 39/156 reads (25%) | called by mutect2, pindel, varscan2
- RTP4 | c.688_689del p.V230Lfs*32 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | called by pindel, varscan2
- TRGC2 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- AGMO | c.18C>A p.A6= | Silent (SNP) | VAF 36/193 reads (19%) | catalogued as COSV100694211; called by muse, mutect2, varscan2
- AMPH | c.1713C>T p.D571= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs1447440426, COSV57743553; called by muse, mutect2, varscan2
- CDH1 | c.1392C>T p.V464= | Silent (SNP) | VAF 74/147 reads (50%) | catalogued as rs373811706; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CEP152 | c.2233T>C p.L745= | Silent (SNP) | VAF 190/300 reads (63%) | catalogued as rs762448733, COSV100358828; called by muse, mutect2, varscan2
- DENND4B | c.3015G>C p.L1005= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100768704; called by muse, mutect2, varscan2
- DNAH17 | c.8679C>T p.I2893= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs1457508546, COSV101102393; called by muse, mutect2, varscan2
- DNAJC2 | c.222C>T p.P74= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as rs751657738, COSV99971803; called by muse, mutect2, varscan2
- EPS8L3 | c.1548C>T p.G516= (on ENST00000361965 / NM_133181.4; = p.G486= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV100719718; called by muse, mutect2, varscan2
- FLG | c.10161C>T p.L3387= | Silent (SNP) | VAF 210/607 reads (35%) | catalogued as COSV100911313, COSV100911608; called by muse, mutect2, varscan2
- MED12L | c.1605G>A p.R535= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99853258; called by muse, mutect2, varscan2
- MEIS1 | c.816T>C p.R272= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV99715257; called by muse, mutect2, varscan2
- MYL4 | c.144C>T p.F48= | Silent (SNP) | VAF 96/260 reads (37%) | catalogued as COSV100733118; called by muse, mutect2, varscan2
- OR3A1 | c.351G>A p.L117= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs776053776, COSV100041698; called by muse, mutect2, varscan2
- PAX7 | c.465G>A p.S155= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV100946812; called by muse, mutect2, varscan2
- PON3 | c.153C>G p.G51= | Silent (SNP) | VAF 107/339 reads (32%) | catalogued as COSV99672505, COSV99672586; called by muse, mutect2, varscan2
- QSOX1 | c.969A>G p.E323= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV100852896; called by muse, mutect2, varscan2
- RPS25 | c.90C>T p.A30= | Silent (SNP) | VAF 66/208 reads (32%) | catalogued as COSV100548770; called by muse, mutect2, varscan2
- SEMA5B | c.960C>T p.R320= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs368230765; called by muse, mutect2, varscan2
- SMR3A | c.30T>G p.L10= | Silent (SNP) | VAF 74/321 reads (23%) | catalogued as COSV99895684; called by muse, mutect2, varscan2
- SPOCK1 | c.360G>A p.G120= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99969126; called by muse, mutect2, varscan2
- STPG2 | c.1326C>A p.S442= | Silent (SNP) | VAF 69/149 reads (46%) | catalogued as COSV54796339, COSV99759512; called by muse, mutect2, varscan2
- TBX20 | c.1038C>G p.L346= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101282381; called by muse, mutect2
- TRAF3IP2 | c.720C>T p.L240= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as COSV100389747, COSV60675457; called by muse, mutect2, varscan2
- WDR12 | c.1224A>G p.K408= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV99651112; called by muse, mutect2, varscan2
- ZAP70 | c.1749C>A p.R583= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV99385543; called by muse, mutect2, varscan2
- CACNB2 | c.214-60984G>A | Intron (SNP) | VAF 53/181 reads (29%) | catalogued as rs1267129849, COSV99994719; called by muse, mutect2, varscan2
- DLG2 | c.205-65879_205-65835del | Intron (DEL) | VAF 57/257 reads (22%) | called by mutect2, pindel
- EPHA10 | chr1:37715878 G>A | 3'Flank (SNP) | VAF 24/75 reads (32%) | catalogued as rs763699429, COSV100361313; called by muse, varscan2
- IGHV1-12 | n.193G>T | RNA (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- LATS1 | c.349-1935A>T | Intron (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
